Surgical pathology report (de-identified scan), TCGA case TCGA-KM-A7Q7, project TCGA-KICH (Kidney Chromophobe), tissue source site NCI Urologic Oncology Branch, specimen TCGA-KM-A7Q7-01B (Primary Tumor).

[page 1 of 4]
Gender: Female	Birth Date:	Admit Date:
Attending:	Admit Protocol:	Age:
		Location:

Surgical Pathology [OrderID:	Final Results
------------------------------	---------------

Surgical Pathology

CASE NUMBER:
DIAGNOSIS:

- Tumor, #1, left kidney (partial nephrectomy): Renal parenchyma showing oncocytosis. Benign smooth muscle tumor. (leiomyoma).
- Tumor, #2, left kidney (partial nephrectomy): Renal cell carcinoma, chromophobe type (small). Fuhman nuclear grade II.
- Tumor, #3, left kidney (partial nephrectomy): Benign smooth muscle tumor (leiomyoma).
- Tumor, #4, left kidney (partial nephrectomy): Renal cell carcinoma, chromophobe type, Fuhman nuclear grade II.
- Tumor, #5, left kidney (partial nephrectomy): Renal cell carcinoma, clear cell type, Fuhman nuclear grade II. Tumor approaches the inked margin.
- Tumor, #5 margin, left kidney (partial nephrectomy): Renal parenchyma with cystic dilatation of tubules.
- Tumor, #6, left kidney (partial nephrectomy): Renal parenchyma with chronic inflammation.
- Tumor, #7, left kidney (partial nephrectomy): Renal cell carcinoma, clear cell type, Fuhman nuclear grade II.
See note. Margins appear to be free of tumor. Smooth muscle proliferation is present outside near the capsule. Oncocytosis.
- Tumor, #8, left kidney (partial nephrectomy): Renal cell carcinoma, clear cell type, Fuhman nuclear grade II. Margins free of tumor.
- Tumor, #10 normal parenchyma, left kidney (resection): Renal parenchyma with cystic dilatation of tubules.
- Rib, left 11th (resection): Gross description only.

ICD-O-3
Carcinoma, renal cell
chromophobe type 8317/3
Site @ Kidney NOS
0649
JW 9/24/13

NOTE: The morphology of the renal tumors and the presence of smooth muscle proliferation suggest the possibility of tuberous sclerosis.

CLINICAL INFORMATION: Allocate Order to Protocol: Brief
Clinical History: Left
renal masses Specimen Taken For Protocol: 01 -
Yes

PROCEDURE: Pre-Operative Diagnosis: left rena mass Post-Operative
Diagnosis: left
renal mass Operative Findings: multiple left renal
masses

[page 2 of 4]
Gender: Female	Birth Date:	Admit Protocol:
Admit Protocol:	Admit Protocol:	Age:
		Location:

Surgical Pathology [OrderID: _____]

Final Results

SPECIMENS SUBMITTED: 1. TUMOR, #1 - Left Kidney
2. TUMOR, #2 - Left Kidney
3. BIOPSY, NOS, LEVEL 5 SECTIONING, Tumor #3 - Left Kidney
4. TUMOR, #4 - Left Kidney
5. TUMOR, #5 - Left Kidney
6. TUMOR, #5 - Left Kidney Margin
7. TUMOR, #6 - Left Kidney
8. TUMOR, #7 - Left Kidney
9. TUMOR, #9 - Left Kidney
10. KIDNEY, LEFT, Normal Peraychmal
11. RIB, Left 11th

GROSS DESCRIPTION:

1. "Tumor #1 left kidney". The specimen consists of a tan tissue fragment measuring 1.2 x 0.5 x 0.5 cm. The specimen consists of a nodule measuring 0.5 cm in diameter with attached renal parenchyma. The specimen is inked black, bisected, revealing a white/tan homogenous cut surface of the nodule. The specimen is entirely submitted in a white cassette labeled _____ for serial sectioning.

2. "Tumor #2". The specimen received fresh OR labeled with the patient's name, medical record number, and "tumor #2" is a 1.2 x 0.9 x 0.6 cm, which is greater than 78% solid. 30% is procured for _____. The procurement was performed by _____ on _____ at _____. Received in Surgical Pathology, the specimen is consistent with the above description. The specimen is entirely submitted in a white cassette labeled _____ for serial sectioning.

3. "Tumor #3 left kidney". The specimen consists of a tan nodule measuring 0.3 cm in diameter. The specimen is inked black and entirely submitted in a white cassette labeled _____ for serial sectioning.

4. Received from OR labeled with the patient's name, medical record number, and "tumor #4 left kidney" is a 4.2 x 2.6 x 0.6 cm specimen with a tumor nodule measuring 2.6 x 3.7 x 2.8 cm with attached renal parenchyma. The specimen is inked black, sectioning of the nodule reveals a homogeneous light brown cut surface. 30% is procured for _____. Representative sections are submitted in white cassettes labeled _____ -4A through 4F serial sectioning. Additional sections are submitted in white cassettes labeled _____ 4G to 4N for serial sectioning (8 more cassettes).

5. Received fresh from OR labeled with the patient's name, medical record number, and "tumor #5 left kidney" is a 2.6 x 2.4 x 1.8 cm tumor nodule which is greater than 70% solid. The specimen is inked black; sectioning reveals a homogeneous light brown cut surface. 75% is procured for Research. Received in Surgical Pathology, the specimen is consistent with the description in the procurement note. The specimen is entirely submitted in white cassettes labeled _____ -5A through 5D for serial sectioning.

[page 3 of 4]
Gender: Female		Birth Date:	Admit Protocol:
Admit Protocol:		Admit Protocol:	Age:
			Location:

Surgical Pathology (OrderID: _____)	Final Results
-------------------------------------	---------------

6. "Tumor #5 left kidney margin" is a tan tissue fragment measuring 1.8 x 1.2 x 0.5 cm. The specimen is inked black and serially sectioned, entirely submitted in a white cassette labeled _____-6 for serial sectioning.

7. "Tumor #6 left kidney". The specimen consists of a tan tissue fragment measuring 0.5 x 0.5 x 0.4 cm. The specimen is inked black and entirely submitted in a white cassette labeled _____-7 for serial sectioning.

8. Received fresh from OR labeled with the patient's name, medical record number, and "tumor #7 left kidney" is a 4.6 x 3.4 x 4.2 cm mass with a tumor nodule measuring 3 x 2.4 x 0.6 cm with attached renal parenchyma. The tumor nodule is greater than 70% solid. The specimen is inked black; sectioning reveals a tan/white cut surface. Approximately _____% procured for _____ Representative sections are submitted in white cassettes labeled _____-8A to 8G for serial sectioning. Additional sections are submitted in white cassettes labeled _____-8H-8L for serial sectioning (5 more cassettes)

9. Received fresh from OR labeled with the patient's name, medical record number, and "tumor #8 left kidney" is a 1.8 x 1.6 x 1.2 cm tissue fragment. There is a 0.7 x 0.7 cm tumor nodule which is greater than 70% solid. The tumor is nodule is light brown in color. _____% was procured for _____ The procurement was performed by _____ Received in Surgical Pathology, the specimen is consistent with the above description. The specimen is entirely submitted in white cassettes labeled _____ and 9B for serial sectioning.

10. Received fresh from OR labeled with the patient's name, medical record number, and "normal parenchyma left kidney" is a 2.6 x 1.7 x 0.7 cm renal tissue. 30% was procured for _____ The procurement was performed by _____ on _____ Received in Surgical Pathology, the specimen is consistent with the above description. The specimen is serially sectioned and representative sections are submitted in a white cassette labeled _____ 10A and 10B for serial sectioning.

11. "Left 11th rib". The specimen consists of two bone fragments measuring 1.2 x 1.2 x 0.3 cm and 2.5 x 0.8 x 0.5 cm, respectively. Gross lesions are identified.

Gross dictated by _____

No consultants

[page 4 of 4]
Gender: Female	Birth Date:	Admit Protocol:
Admit Protocol:	Admit Protocol:	Location:

Surgical Pathology [OrderID:	Final Results
------------------------------	---------------

, MD, ATTENDING STAFF PATHOLOGIST

Criteria	hw 9/16/13	Yes	No
Prior Malignancy History	② K. Yang clear cell	✓	
Dual Synchronous Primary	② K. Yang clear cell	✓	

Source: NCI Genomic Data Commons file 4542ad50-1fd2-4758-a808-fc2fe66f4cb0 (TCGA-KM-A7Q7.7FD7340E-0F3A-484E-A5CF-5165BE5E9578.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).